Somatic mutation profile of tumor specimen TCGA-CN-6012-01A (aliquot TCGA-CN-6012-01A-11D-1683-08) from TCGA case TCGA-CN-6012, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.5 years (24,286 days).
Specimen TCGA-CN-6012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 559e0079-b649-493d-ad03-2ba15b628794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6012-10A (Blood Derived Normal), aliquot TCGA-CN-6012-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/193c5118-4540-4473-9751-b60089bb9ddb

The open-access MAF lists 117 somatic variants for this specimen: 95 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 21, Nonsense Mutation 12, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Translation Start Site 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.377A>C p.Y126S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM115636, COSV52689293, COSV52760406, COSV52970718; called by muse, mutect2
- ABTB1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149260862; called by muse, mutect2, varscan2
- ADAMTS3 | c.2860C>A p.R954S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs753521781, COSV99712377; called by muse, mutect2, varscan2
- ADAMTS5 | c.2220G>C p.K740N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV99538508; called by muse, mutect2
- ANO3 | c.576G>C p.L192F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99886467; called by muse, mutect2, varscan2
- ARHGAP35 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV101351884; called by muse, mutect2, varscan2
- ATP11A | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99370247; called by muse, mutect2
- ATXN10 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs766423755, COSV99426839; called by muse, mutect2, varscan2
- BRD1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs778747819, COSV53460096; called by muse, mutect2, varscan2
- CAGE1 | c.1762C>T p.H588Y (on ENST00000512086; = p.H452Y on NM_205864.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as rs1047765887, COSV99700280; called by muse, mutect2, varscan2
- CAPN3 | c.2398G>C p.D800H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99783320; called by muse, mutect2, varscan2
- CAPNS2 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100045457; called by muse, mutect2
- CCDC170 | c.261C>G p.Y87* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99498990; called by muse, mutect2, varscan2
- CCDC170 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 39/123 reads (32%) | catalogued as COSV99498992; called by muse, mutect2, varscan2
- CELF4 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV100612162; called by muse, mutect2, varscan2
- CETN3 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99300673; called by muse, mutect2, varscan2
- CNTNAP1 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV52850176; called by muse, mutect2
- COL6A6 | c.6008C>T p.T2003I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as rs1006132624, COSV100651078; called by muse, mutect2, varscan2
- COPS5 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV100770048; called by muse, mutect2
- CTHRC1 | c.656C>G p.S219* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | catalogued as COSV100373081, COSV57716048; called by muse, mutect2
- CXCL12 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100639089; called by muse, mutect2, varscan2
- DIP2C | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.523); catalogued as rs368102774; called by muse, mutect2, varscan2
- DZIP3 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | catalogued as COSV100848128; called by muse, mutect2, varscan2
- ELAVL3 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs571838282, COSV63646597; called by mutect2, varscan2
- ERCC6 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs760618206, COSV100876333, COSV63395218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESRRB | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1477346091, COSV55062198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EXO1 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371763760, COSV100800264; called by muse, varscan2
- FAM102B | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as COSV100899426; called by muse, mutect2, varscan2
- FAT1 | c.8513C>A p.S2838* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV101499686, COSV71672363, COSV99081604; called by muse, mutect2, varscan2
- FMN2 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs867051143, COSV100147729; called by muse, mutect2
- GPNMB | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99326913; called by muse, mutect2, varscan2
- GPR101 | c.404A>G p.H135R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99981291; called by muse, mutect2, varscan2
- GRIA1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as rs1404893868, COSV53600380; called by muse, mutect2
- GRPR | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1024982825, COSV100977710; called by muse, mutect2, varscan2
- HADHA | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs766663662, COSV101024273; called by muse, mutect2, varscan2
- HFM1 | c.4156G>A p.E1386K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99647042; called by muse, mutect2, varscan2
- HFM1 | c.3991G>C p.E1331Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.136); catalogued as COSV99647044; called by muse, mutect2
- HPS3 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV99937708; called by muse, mutect2
- HSP90B1 | c.1831G>T p.V611F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV100236210, COSV100236825; called by muse, mutect2, varscan2
- IGHG4 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs1389090917; called by muse, mutect2
- IL1RAPL2 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100782197; called by muse, mutect2, varscan2
- IL27RA | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV99652484; called by muse, mutect2, varscan2
- IRX1 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100116864; called by muse, mutect2, varscan2
- ITGA8 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 27/290 reads (9%) | catalogued as rs1358323528, COSV65237036; called by muse, mutect2
- KEAP1 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50418315, COSV99408002; called by muse, mutect2, varscan2
- KRT77 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV100527319; called by muse, mutect2, varscan2
- LGALS1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99313832; called by muse, mutect2, varscan2
- MAGEF1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100511063; called by muse, mutect2, varscan2
- MEX3A | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101348975, COSV68479208; called by muse, mutect2
- MORC3 | c.2109del p.L704Sfs*29 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | catalogued as COSV101264895; called by mutect2, pindel, varscan2
- MPO | c.1969G>A p.V657M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774394797, COSV51858210; called by muse, mutect2, varscan2
- MRC1 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1311672355; called by muse, mutect2, varscan2
- MRPS30 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99138186; called by muse, mutect2
- NEB | c.18422G>A p.R6141H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs369514998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFS1 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463021083, COSV100148826; called by muse, varscan2
- NLGN4X | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.458); catalogued as COSV99324473; called by muse, mutect2, varscan2
- NOTCH4 | c.3070C>A p.H1024N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100901205; called by muse, mutect2
- NXPH3 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100165605; called by muse, mutect2, varscan2
- OR11G2 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV100640079, COSV62133089; called by muse, mutect2, varscan2
- OR5T2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 46/107 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100507124; called by muse, mutect2, varscan2
- OR5V1 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV101011523; called by muse, mutect2, varscan2
- PCDHAC1 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99170181; called by muse, mutect2, varscan2
- POLQ | c.6943C>T p.R2315* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as rs765178927, COSV51761541; called by muse, mutect2, varscan2
- PPFIA1 | c.815G>C p.R272P | Missense Mutation (SNP) | VAF 88/1362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99558172; called by muse, mutect2
- PRDM9 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as rs773518946, COSV99691486; called by muse, mutect2, varscan2
- PRR16 | c.256G>T p.G86C (on ENST00000407149 / NM_001300783.2; = p.G63C on NM_016644.2) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs763004804, COSV101088417; called by muse, mutect2, varscan2
- PRUNE2 | c.2448G>A p.W816* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs267602277, COSV65037713; called by muse, mutect2, varscan2
- PTCH1 | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100110312, COSV59494584; called by muse, mutect2, varscan2
- RAB3IP | c.1250A>C p.Y417S (on ENST00000550536 / NM_175623.4; = p.Y401S on NM_022456.5) | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99923776; called by muse, mutect2, varscan2
- RNF148 | c.904A>G p.I302V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.39); catalogued as COSV100411806; called by muse, mutect2
- SCP2D1 | c.140T>A p.V47E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99602236; called by muse, mutect2, varscan2
- SH3GL1 | c.114+2T>C p.X38_splice | Splice Site (SNP) | VAF 37/297 reads (12%) | catalogued as COSV99522698; called by muse, mutect2, varscan2
- SLC9A3 | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99376757; called by mutect2, varscan2
- SLITRK2 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as COSV100158321, COSV59423947; called by muse, mutect2, varscan2
- SORCS1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV99542973; called by muse, mutect2, varscan2
- SYMPK | c.3319G>A p.E1107K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55574488; called by muse, mutect2
- TAS2R14 | c.625C>G p.R209G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs779911373, COSV101115878; called by muse, mutect2, varscan2
- TMEM266 | c.383T>C p.F128S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101189680; called by muse, mutect2, varscan2
- TMEM63C | c.1983C>G p.I661M | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100029874; called by muse, mutect2, varscan2
- TRARG1 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100416991; called by muse, mutect2, varscan2
- TRERF1 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100551922; called by muse, mutect2
- TUBB6 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100481244, COSV58353872; called by muse, mutect2
- UBXN7 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV99581909; called by muse, mutect2, varscan2
- ZDHHC23 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100362282; called by muse, mutect2, varscan2
- ZFP14 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 33/218 reads (15%) | catalogued as COSV99525381; called by muse, mutect2, varscan2
- ZNF570 | c.1553G>A p.R518K | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs750120532, COSV57580180; called by muse, mutect2, varscan2
- ZNF671 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV58053152; called by muse, mutect2, varscan2
- ZNF790 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as rs772363425, COSV63213089; called by muse, mutect2, varscan2
- FCGBP | c.10808G>T p.G3603V | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GPR179 | c.5891C>T p.T1964I (on ENST00000621958; = p.T1963I on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP4R1 | c.2021dup p.D674Efs*35 (on ENST00000400556 / NM_001042388.3; = p.D657Efs*35 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 115/297 reads (39%) | called by mutect2, pindel, varscan2
- SRRT | c.43_66del p.K15_D22del | In Frame Del (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- SYMPK | c.3320A>T p.E1107V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TEX19 | c.281dup p.S95Lfs*2 | Frame Shift Ins (INS) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- ALPG | c.1365C>T p.D455= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV54968189; called by muse, mutect2, varscan2
- CDH10 | c.384C>T p.R128= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs768905224, COSV52568657, COSV52580692; called by muse, mutect2, varscan2
- CDH18 | c.1863C>T p.L621= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1554023124, COSV99938972; called by muse, mutect2, varscan2
- CELSR1 | c.8682C>T p.R2894= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs768271831, COSV99420503; called by muse, mutect2, varscan2
- CUBN | c.9819C>T p.I3273= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100913720; called by muse, mutect2, varscan2
- DHX15 | c.2343C>T p.D781= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100391839; called by muse, mutect2, varscan2
- EIF2AK4 | c.4293C>T p.D1431= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99775534; called by muse, mutect2, varscan2
- EML1 | c.1290T>G p.G430= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV99215796; called by muse, mutect2, varscan2
- FARP1 | c.1404G>A p.Q468= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100132349; called by muse, mutect2, varscan2
- FCGR2B | c.483C>G p.V161= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99375447; called by muse, mutect2, varscan2
- OR5J2 | c.735G>T p.L245= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100399289, COSV100399308; called by muse, mutect2, varscan2
- PIK3CD | c.2685C>T p.H895= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as COSV100740615; called by muse, mutect2, varscan2
- PKDREJ | c.5419C>T p.L1807= | Silent (SNP) | VAF 31/305 reads (10%) | catalogued as COSV99479663; called by muse, mutect2, varscan2
- PPRC1 | c.2145C>T p.S715= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV53384779; called by muse, mutect2, varscan2
- RIF1 | c.933A>G p.L311= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1231939322, COSV54614969; called by muse, mutect2, varscan2
- SHOX2 | c.519G>A p.L173= (on ENST00000441443 / NM_006884.3; = p.L197= on NM_003030.4) | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as COSV67464955; called by muse, mutect2
- SLC16A7 | c.1074C>G p.L358= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV99676963; called by muse, mutect2, varscan2
- SLC2A10 | c.189G>T p.L63= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV63715074; called by muse, mutect2, varscan2
- SLC6A13 | c.1296G>C p.L432= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100570105; called by muse, mutect2
- SYNE2 | c.5713C>T p.L1905= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100648613; called by muse, mutect2, varscan2
- ZNF433 | c.1470C>A p.P490= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100795060; called by muse, mutect2, varscan2
- FAM228A | c.*1G>A | 3'UTR (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99722692; called by muse, mutect2, varscan2
